CCDI case PBCCKU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d14e9824-c3fb-4ac7-b755-4cd0b5d8a130

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,689 days).

Biospecimens (3 samples)
- Sample 0DOBSU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOBT8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOBTF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
